Somatic mutation profile of tumor specimen ALCH-B2D8-TTP1-A (aliquot ALCH-B2D8-TTP1-A-8-0-D-A76I-36) from ALCHEMIST case ALCH-B2D8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,065 days).
Specimen ALCH-B2D8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d3c9806-fb7a-4eaf-9947-a9aace5e5c6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2D8-NB1-A (Blood Derived Normal), aliquot ALCH-B2D8-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34c5f21e-2318-4292-a4a7-5dd1e7c71b99

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Intron 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 45/425 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV59259218, COSV59259530, COSV59268643; called by muse, mutect2
- ATP1A1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1429384765, COSV55189682, COSV55192203; called by muse, mutect2
- KCTD8 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV63599348; called by muse, mutect2
- RBM10 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 44/237 reads (19%) | catalogued as COSV61309517; called by muse, mutect2, varscan2
- TIGD3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs1414824690; called by muse, mutect2
- ZXDC | c.2304C>G p.S768R | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV101071566, COSV67629088; called by muse, mutect2
- ANXA6 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 22/679 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP9 | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- DIAPH1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EIF5 | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 24/441 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- F12 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2A | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRN | c.1574A>T p.H525L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- HDAC3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 56/472 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC2 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NUP107 | c.2535A>C p.Q845H | Missense Mutation (SNP) | VAF 60/490 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- PABPC4L | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 47/539 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLK2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2
- TMEM259 | c.552C>G p.S184R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- TOPBP1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- GFOD2 | c.910C>T p.L304= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- GTF2H1 | c.1185A>T p.A395= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- PCDHA12 | c.1830G>A p.E610= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- SYPL2 | c.576A>C p.S192= | Silent (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- ZBTB38 | c.942A>G p.G314= | Silent (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- FBN2 | c.952+4151T>A | Intron (SNP) | VAF 50/778 reads (6%) | called by muse, mutect2
- MFN2 | c.*1842G>T | 3'UTR (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2
- WNK4 | c.2295+155A>G | Intron (SNP) | VAF 9/166 reads (5%) | catalogued as rs1432688256; called by muse, mutect2
